Somatic mutation profile of tumor specimen MP2PRT-PARPVS-TMP1-A (aliquot MP2PRT-PARPVS-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPVS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,233 days).
Specimen MP2PRT-PARPVS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64c8fe97-690c-43f4-8cf8-c99eee1374c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPVS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPVS-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac4cc68b-7085-4128-981f-6c24159f75bc

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 23, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYH7 | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs397516088, CM031268, COSV62516328, COSV62522137; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- APOB | c.9775G>C p.E3259Q | Missense Mutation (SNP) | VAF 24/597 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV51945459; called by muse, mutect2
- CRISP2 | c.651G>C p.L217F | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV59253065; called by muse, mutect2
- DGUOK | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 43/680 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs140284468, COSV99903561; called by muse, mutect2
- H3-3B | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 24/563 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV54666757; called by muse, mutect2
- HTR2B | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 13/488 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV51449452; called by muse, mutect2
- MYOCD | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 15/404 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV100590801; called by muse, mutect2
- RASSF4 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 23/780 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53573477; called by muse, mutect2
- SMARCD1 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV56547271; called by muse, mutect2
- VNN2 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 78/301 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.11); catalogued as rs1204346828; called by muse, mutect2, varscan2
- AAK1 | c.2222C>G p.S741* | Nonsense Mutation (SNP) | VAF 22/398 reads (6%) | called by muse, mutect2
- CDH24 | c.137G>C p.W46S | Missense Mutation (SNP) | VAF 24/652 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- FSD2 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPD1L | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIPAP1 | c.1876G>C p.D626H | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2
- HES5 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 95/985 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); called by muse, mutect2
- KDM5C | c.3872G>A p.R1291H | Missense Mutation (SNP) | VAF 288/455 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MYO1C | c.2337G>C p.K779N (on ENST00000648651 / NM_001080779.2; = p.K744N on NM_033375.5) | Missense Mutation (SNP) | VAF 46/753 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2
- PAGE4 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2
- PNKP | c.390G>C p.K130N | Missense Mutation (SNP) | VAF 35/650 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.045); called by muse, mutect2
- PRDX6 | c.43G>C p.E15Q | Missense Mutation (SNP) | VAF 33/686 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2
- RAPH1 | c.629C>G p.S210C | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- RNF43 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 40/637 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.319); called by muse, mutect2
- SLC2A9 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 113/442 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ANK2 | c.7380G>C p.L2460= | Silent (SNP) | VAF 145/478 reads (30%) | called by muse, mutect2, varscan2
- EEF1G | c.93G>A p.V31= | Silent (SNP) | VAF 147/549 reads (27%) | called by muse, mutect2, varscan2
- FGD5 | c.1914C>T p.I638= | Silent (SNP) | VAF 138/431 reads (32%) | catalogued as rs1461008804, COSV53246819; called by muse, mutect2, varscan2
- MYRIP | c.1725C>G p.L575= | Silent (SNP) | VAF 32/468 reads (7%) | called by muse, mutect2
- PSMD6 | c.57C>T p.I19= | Silent (SNP) | VAF 105/873 reads (12%) | catalogued as COSV55759739; called by muse, mutect2, varscan2
- RYR3 | c.45G>A p.L15= | Silent (SNP) | VAF 46/538 reads (9%) | catalogued as COSV66797194; called by muse, mutect2
